Somatic mutation profile of tumor specimen MMRF_1037_1_BM_CD138pos (aliquot MMRF_1037_1_BM_CD138pos_T2_TSE61_K02458) from MMRF case MMRF_1037, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.3 years (29,704 days).
Specimen MMRF_1037_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da1a54af-c468-4532-9003-72c52dcfe6c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1037_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1037_1_PB_Whole_C1_TSE61_K02451; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c551d35-a496-4bf7-ac17-37eeae8f139d

The open-access MAF lists 127 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 37, Silent 17, Intron 4, RNA 4, Frame Shift Del 3, 3'Flank 3, 5'UTR 3, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACTN2 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769126818, COSV63974508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs1481774294; called by muse, mutect2, varscan2
- BOD1L1 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV50015460; called by muse, mutect2, varscan2
- DLX1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1040620446, COSV100543224; called by muse, mutect2, varscan2
- DNAH6 | c.1744A>C p.S582R | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52887588; called by muse, mutect2, varscan2
- FBN3 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs375756610; called by muse, mutect2, varscan2
- H2BC13 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV62440634; called by muse, mutect2, varscan2
- JAKMIP3 | c.1810C>A p.Q604K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV53826962; called by muse, mutect2, varscan2
- KCNH2 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.782); catalogued as rs143335921; called by muse, mutect2, varscan2
- KCTD15 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.34); catalogued as COSV52289569; called by muse, mutect2, varscan2
- KRT27 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV56971611; called by muse, mutect2, varscan2
- LCT | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1351816503, COSV51548479; called by muse, mutect2
- LRRK1 | c.3754G>A p.G1252S | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs373729202, COSV52600182; called by muse, mutect2, varscan2
- NOTCH3 | c.5569C>T p.R1857W | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752169336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4C6 | c.129T>G p.I43M | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100051660; called by muse, mutect2
- OSMR | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1247046563; called by muse, mutect2, varscan2
- PPP4R3C | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 149/155 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1244321936, COSV101297302; called by muse, mutect2, varscan2
- PRLHR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs945808344, COSV53302772; called by muse, mutect2
- PRMT7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs747609401; called by muse, mutect2, varscan2
- SLC18B1 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs747717785; called by muse, mutect2, varscan2
- TBC1D31 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV99783262; called by muse, mutect2, varscan2
- ZNF502 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1381199215; called by muse, mutect2
- ZNF521 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248818093, COSV64133304; called by muse, mutect2, varscan2
- ADAMTS2 | c.2668G>C p.V890L | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ANO4 | c.1154G>A p.S385N (on ENST00000392977 / NM_001286615.2; = p.S350N on NM_178826.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP13A4 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2
- BPTF | c.6970C>T p.Q2324* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CCDC15 | c.1437T>G p.F479L | Missense Mutation (SNP) | VAF 101/640 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNB1 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP221 | c.1028del p.L343Wfs*13 | Frame Shift Del (DEL) | VAF 125/223 reads (56%) | called by mutect2, pindel, varscan2
- CHD7 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CTTNBP2 | c.2840A>C p.N947T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FBN2 | c.930T>A p.S310R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FBXO10 | c.963C>G p.S321R | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.276); called by muse, mutect2
- H2BC5 | c.195del p.F66Sfs*69 (on ENST00000289316 / NM_138720.2; = p.F66Sfs*66 on NM_021063.4) | Frame Shift Del (DEL) | VAF 119/279 reads (43%) | called by mutect2, pindel, varscan2
- IRS2 | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAG1 | c.634T>A p.C212S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNT2 | c.2194T>A p.L732I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KIF14 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.025); called by muse, mutect2
- LCTL | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); called by muse, mutect2
- LRBA | c.6989G>T p.G2330V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRTM4 | c.1189T>G p.S397A | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSX2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2
- MUC15 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); called by muse, mutect2
- MYH14 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- OR4C13 | c.308A>T p.H103L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR5D13 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- PDZD4 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH2R | c.577A>T p.S193C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN9A | c.4263A>G p.V1421= (on ENST00000303354; = p.V1410= on NM_002977.3) | Splice Region (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- SFRP4 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- SLC7A13 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENT5C | c.573_577del p.L191Ffs*4 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- VCPIP1 | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VPS4B | c.772T>C p.F258L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ZBTB38 | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF285 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 181/755 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF492 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 308/682 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRA1 | c.567C>T p.V189= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs996694716; called by muse, mutect2, varscan2
- CD2AP | c.531G>A p.Q177= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV63759880; called by muse, mutect2, varscan2
- CDH10 | c.1794C>T p.C598= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- CNBD1 | c.825G>A p.S275= | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as rs374378962; called by muse, mutect2, varscan2
- FAM184A | c.1140C>G p.V380= | Silent (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- FER1L6 | c.1770G>A p.Q590= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- GPC5 | c.1593A>T p.V531= | Silent (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- ITIH2 | c.1536C>T p.D512= | Silent (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- KIAA0319 | c.621G>A p.A207= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs746122024, COSV65501755; called by muse, mutect2, varscan2
- LCOR | c.852G>A p.T284= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs753194505, COSV63632201; called by muse, mutect2, varscan2
- MBOAT7 | c.633C>A p.L211= | Silent (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- NOC4L | c.675C>T p.T225= | Silent (SNP) | VAF 79/158 reads (50%) | catalogued as rs755304546, COSV100223144, COSV57959416; called by muse, mutect2, varscan2
- RFX6 | c.423A>G p.P141= | Silent (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- SYT3 | c.1434G>A p.E478= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV58898996; called by muse, mutect2, varscan2
- WDR1 | c.1029C>T p.D343= (on ENST00000382452; = p.D203= on NM_005112.5) | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs763307377; called by muse, mutect2, varscan2
- ZNF648 | c.1416C>T p.G472= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV60570786; called by muse, mutect2, varscan2
- ZNF814 | c.1836T>A p.S612= | Silent (SNP) | VAF 44/1057 reads (4%) | called by muse, mutect2
- AC139769.1 | n.214-4011T>C | Intron (SNP) | VAF 546/1187 reads (46%) | called by muse, mutect2, varscan2
- ADAM12 | c.*511T>A | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- AFF2 | c.*6156dup | 3'UTR (INS) | VAF 20/28 reads (71%) | catalogued as rs782725794; called by mutect2, varscan2
- ARHGAP42 | c.*4100T>C | 3'UTR (SNP) | VAF 105/196 reads (54%) | called by muse, mutect2, varscan2
- C1QL3 | c.*480T>G | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- CADPS | c.-21C>T | 5'UTR (SNP) | VAF 37/111 reads (33%) | catalogued as rs754525643; called by muse, mutect2, varscan2
- CNTNAP3 | c.*6C>T | 3'UTR (SNP) | VAF 21/827 reads (3%) | called by muse, mutect2
- DDIT4L | c.*810T>A | 3'UTR (SNP) | VAF 85/158 reads (54%) | called by muse, mutect2, varscan2
- EHD3 | c.*916A>T | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- ESM1 | c.*1361G>A | 3'UTR (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- FAM238A | n.600G>A | RNA (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- FGF12 | chr3:192142405 G>A | 3'Flank (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- FLT1 | c.1969+1505G>T | Intron (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- GNG4 | chr1:235549319 del AGGGGAAGGTAAGGAAGAGAGGAGGAAAAGGAAAAGGAG | 3'Flank (DEL) | VAF 42/109 reads (39%) | called by mutect2, pindel
- GPR107 | c.*2367T>C | 3'UTR (SNP) | VAF 49/131 reads (37%) | called by muse, mutect2, varscan2
- GUSBP1 | n.4037T>C | RNA (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.*1490G>A | 3'UTR (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- IGF2R | c.6656-732T>G | Intron (SNP) | VAF 136/275 reads (49%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*719G>A | 3'UTR (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- KCNK2 | c.*1256G>T | 3'UTR (SNP) | VAF 7/161 reads (4%) | catalogued as COSV101222202; called by muse, mutect2
- KHDRBS3 | c.*119G>A | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- LARP1B | c.*212C>T | 3'UTR (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- LRAT | c.*3687A>C | 3'UTR (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- LRP6 | c.*3661G>A | 3'UTR (SNP) | VAF 46/102 reads (45%) | catalogued as rs1299216550; called by muse, mutect2, varscan2
- LRRTM3 | c.*2640G>C | 3'UTR (SNP) | VAF 82/153 reads (54%) | called by muse, mutect2, varscan2
- MFN2 | c.*340A>T | 3'UTR (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20396511 G>A | 3'Flank (SNP) | VAF 29/130 reads (22%) | catalogued as rs1396738781; called by muse, mutect2, varscan2
- MYO1E | c.-47_-46delinsT | 5'UTR (DEL) | VAF 47/111 reads (42%) | called by pindel, varscan2*
- NIPSNAP3B | c.*4231A>C | 3'UTR (SNP) | VAF 78/131 reads (60%) | called by muse, mutect2, varscan2
- OTUB2 | c.*673C>G | 3'UTR (SNP) | VAF 31/61 reads (51%) | catalogued as rs1005659912; called by muse, mutect2, varscan2
- PFN1 | c.*109del | 3'UTR (DEL) | VAF 69/188 reads (37%) | called by mutect2, pindel, varscan2
- PLCB1 | c.*1855dup | 3'UTR (INS) | VAF 25/74 reads (34%) | catalogued as rs760187225; called by mutect2, varscan2
- PLXNA2 | c.*2055del | 3'UTR (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- PTGFR | c.-148+38684A>T | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- PWWP2B | c.*538G>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- RFLNA | c.-57G>A | 5'UTR (SNP) | VAF 6/21 reads (29%) | catalogued as rs191576774; called by muse, mutect2
- RND3 | c.*1248G>A | 3'UTR (SNP) | VAF 46/121 reads (38%) | catalogued as rs536945240; called by muse, mutect2, varscan2
- SLC46A1 | c.*3607G>T | 3'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- SRCIN1 | c.*317C>T | 3'UTR (SNP) | VAF 59/107 reads (55%) | called by muse, mutect2, varscan2
- TMEM132C | c.*489dup | 3'UTR (INS) | VAF 64/133 reads (48%) | catalogued as rs1043042144; called by mutect2, varscan2
- TMEM232 | c.*267T>A | 3'UTR (SNP) | VAF 85/144 reads (59%) | called by muse, mutect2, varscan2
- TNKS | c.*5199G>A | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*950_*982del | 3'UTR (DEL) | VAF 33/57 reads (58%) | called by mutect2, pindel
- UHRF1BP1 | c.*4981A>T | 3'UTR (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- WDR82 | c.*19A>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
- XYLT1 | c.*17T>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | catalogued as rs538885348; called by muse, mutect2, varscan2
- ZNF252P | n.3309G>C | RNA (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- ZNF271P | n.2159A>T | RNA (SNP) | VAF 70/120 reads (58%) | called by muse, mutect2, varscan2
- ZNF335 | c.*244G>T | 3'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as rs182493979; called by muse, mutect2, varscan2
- ZNF578 | c.*2509G>T | 3'UTR (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- ZNF667 | c.*972_*973del | 3'UTR (DEL) | VAF 109/248 reads (44%) | called by pindel, varscan2
